Somatic mutation profile of tumor specimen 0DB9NY from CCDI case PBBKPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (783 days).
Specimen 0DB9NY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3de49bb-4bff-4ef8-9c4c-f29e2439a3cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB9NV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42cff6b5-fcf6-412e-a72c-1e57a7c0471b

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT4 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 137/411 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs749136382, COSV57335968; called by muse, mutect2, varscan2
- C12orf50 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 211/610 reads (35%) | catalogued as rs762391760, COSV100072233; called by muse, mutect2, varscan2
- DICER1 | c.5532G>C p.K1844N | Missense Mutation (SNP) | VAF 32/1092 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1360182417; called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 71/910 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- HCFC1 | c.4222C>G p.L1408V | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRIM39 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 232/591 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 48/1054 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- BRIX1 | c.1059A>G p.K353= | Silent (SNP) | VAF 242/562 reads (43%) | catalogued as rs764873610; called by muse, mutect2, varscan2
- HCFC1 | c.4221G>T p.L1407= | Silent (SNP) | VAF 83/182 reads (46%) | called by muse, mutect2, varscan2
- TSSC4 | c.51C>T p.H17= | Silent (SNP) | VAF 167/624 reads (27%) | catalogued as rs772817315, COSV50169730; called by muse, mutect2, varscan2
- KIAA1328 | c.1232+16740G>A | Intron (SNP) | VAF 8/242 reads (3%) | called by muse, mutect2
- SETD3 | c.849+38A>G | Intron (SNP) | VAF 34/147 reads (23%) | called by muse, mutect2, varscan2
